Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3554, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3554-01A (Primary Tumor).

Diagnosis:

Resected ileocolic material displaying in the colon ascendens, located 2 cm distal to the ileocecal valve, an adenocarcinoma of colorectal type measuring a maximum of 4 cm in diameter, ulcerated, moderately differentiated and with infiltration of the perifocal adipose tissue. Tumor-free lymph nodes in this region. Tumor-free small and large intestine resection margins. Tumor-free mesenteric resection margin. Tumor-free appendix. Tumor-free omental adipose tissue.

Tumor stage therefore pT3, pN0 (0/39) pMX; G2, L0, V0, local R0

Source: NCI Genomic Data Commons file 004e158d-aac7-461f-be6e-f3bdcde20224 (TCGA-AA-3554.3769BE1D-4A1A-4279-A7E0-F4B828BCDDC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).